CCDI case PBCRFZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/7ba7eed6-987b-4298-af85-5b4a390e66b8

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Pineal gland; Age at diagnosis: 1.6 years (585 days).

Biospecimens (3 samples)
- Sample 0DXAQH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXAQO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DXAR1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
